Somatic mutation profile of tumor specimen HTMCP-03-06-02218-01A (aliquot HTMCP-03-06-02218-01A-01D-6194) from CGCI case HTMCP-03-06-02218, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Age at diagnosis: 53.3 years (19,462 days).
Specimen HTMCP-03-06-02218-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e33b88ac-e697-47ac-a1fd-e36b284c0241.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02218-10A (Blood Derived Normal), aliquot HTMCP-03-06-02218-10A-01D-6194; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f77b60d0-a0ba-4a9d-93ea-00082bae06ac

The open-access MAF lists 84 somatic variants for this specimen: 63 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 16, Nonsense Mutation 5, Intron 3, Frame Shift Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.4156G>A p.V1386I | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as rs377479549; called by muse, mutect2
- ADGRL3 | c.4607A>T p.N1536I (on ENST00000506720 / NM_001322402.2; = p.N1425I on NM_015236.6) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as COSV72229989; called by muse, mutect2
- BRWD3 | c.2418T>A p.N806K | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.028); catalogued as COSV100955876, COSV64749231; called by muse, mutect2
- C3 | c.2453C>T p.A818V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1167343514; called by muse, mutect2, varscan2
- CCDC168 | c.19088T>A p.V6363D | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs565344019; called by muse, mutect2
- CEP250 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771260667, COSV61172329; called by muse, mutect2, varscan2
- COLGALT2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768723326, COSV62727701; called by muse, mutect2, varscan2
- EIF4A1 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs1036532248; called by muse, mutect2
- ERBB4 | c.2779C>T p.R927* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as rs537458255, COSV61460348; called by muse, mutect2, varscan2
- F8 | c.4344A>C p.Q1448H | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV64274256; called by muse, mutect2, varscan2
- GABRB3 | c.370T>G p.L124V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.129); catalogued as COSV100161039, COSV54673184; called by muse, mutect2
- IQSEC1 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1237374778; called by muse, mutect2, varscan2
- LAMA2 | c.6470C>T p.T2157I | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1411280799; called by muse, mutect2, varscan2
- MED12L | c.2893G>A p.V965M | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV99853082; called by muse, mutect2, varscan2
- MGA | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV54958630, COSV99581827; called by muse, mutect2, varscan2
- OR2M5 | c.115T>C p.F39L | Missense Mutation (SNP) | VAF 31/360 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63546280; called by muse, mutect2
- PFKFB1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 27/182 reads (15%) | PolyPhen benign (0.003); catalogued as rs1302348868; called by muse, mutect2, varscan2
- PKD2L2 | c.1674G>C p.E558D | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.058); catalogued as COSV50365535; called by muse, mutect2, varscan2
- PKHD1 | c.3779C>T p.A1260V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as rs112182862, COSV100580961; ClinVar: uncertain significance; called by mutect2, varscan2
- PLEKHH2 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs149016340; called by muse, mutect2, varscan2
- PZP | c.1967C>G p.S656* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | catalogued as COSV54358833; called by muse, mutect2, varscan2
- RTN2 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV55593302; called by muse, mutect2, varscan2
- SERPINI1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as rs1204961300, COSV55515365; called by muse, varscan2
- SFSWAP | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1566007654, COSV99906073; called by muse, mutect2, varscan2
- SHROOM4 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782478370, COSV56784824; called by muse, varscan2
- SLIT3 | c.4183G>A p.E1395K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.698); catalogued as rs372131562; called by muse, mutect2, varscan2
- SLITRK2 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1313895330, COSV59426603; called by muse, mutect2
- TCERG1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs372905217; called by muse, mutect2, varscan2
- TMC5 | c.1026T>G p.C342W | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.094); catalogued as rs959149916; called by muse, mutect2, varscan2
- TRAPPC9 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs769467379, COSV66894126; called by muse, mutect2, varscan2
- TSHZ1 | c.632C>T p.T211M (on ENST00000580243 / NM_001308210.2; = p.T166M on NM_005786.6) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as rs756592040; called by mutect2, varscan2
- ZNF544 | c.2137G>T p.E713* | Nonsense Mutation (SNP) | VAF 37/129 reads (29%) | catalogued as COSV54135648; called by muse, mutect2, varscan2
- ZNF875 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs373644320; called by muse, mutect2, varscan2
- ADGRV1 | c.15958G>A p.D5320N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COL4A1 | c.3958G>T p.G1320C | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DIAPH3 | c.1589T>G p.L530W (on ENST00000400324 / NM_001042517.2; = p.L267W on NM_030932.3) | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DNAH11 | c.5794T>A p.Y1932N | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EXOC6 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAM161B | c.1523C>T p.S508F (on ENST00000651776; = p.S445F on NM_152445.3) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- FAT1 | c.3563C>G p.S1188* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- GFM1 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- GLUD2 | c.1131C>G p.D377E | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- KIAA1210 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KIF16B | c.1076T>C p.I359T | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- LAMA3 | c.7678G>C p.G2560R (on ENST00000313654 / NM_198129.4; = p.G951R on NM_000227.6) | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP2 | c.13780G>C p.E4594Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- MORC4 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NLRP4 | c.2758A>T p.S920C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PAFAH1B2 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.425); called by muse, mutect2
- PCDH9 | c.908T>C p.F303S | Missense Mutation (SNP) | VAF 25/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHKA2 | c.2320C>T p.Q774* | Nonsense Mutation (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- PIK3CA | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- RGPD3 | c.3526C>T p.L1176F | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- SEMA3A | c.1556T>A p.I519N | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SLC9A9 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- SNX13 | c.505_508del p.L169Efs*10 | Frame Shift Del (DEL) | VAF 34/274 reads (12%) | called by mutect2, pindel, varscan2
- SOX5 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TAF5L | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- U2SURP | c.1990C>A p.P664T | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- USP34 | c.9571G>C p.E3191Q | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZEB2 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF521 | c.1325G>T p.C442F | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF649 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAMTS20 | c.1596A>C p.T532= | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- CDC16 | c.441C>A p.T147= | Silent (SNP) | VAF 107/282 reads (38%) | called by muse, mutect2, varscan2
- FAM186A | c.6465C>T p.F2155= | Silent (SNP) | VAF 50/148 reads (34%) | called by muse, mutect2, varscan2
- FGD5 | c.4035G>A p.K1345= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as rs745521396; called by muse, mutect2, varscan2
- GRIA3 | c.2568C>T p.R856= | Silent (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- MAGEC3 | c.678C>T p.F226= | Silent (SNP) | VAF 28/225 reads (12%) | called by muse, mutect2, varscan2
- RYR2 | c.606C>T p.H202= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs1438256315, COSV63691206; called by muse, mutect2
- SATB1 | c.1716C>T p.N572= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs780251058, COSV100113319, COSV58673929; called by muse, mutect2, varscan2
- SHROOM4 | c.516C>T p.S172= | Silent (SNP) | VAF 10/125 reads (8%) | catalogued as rs782439211, COSV99173447; called by muse, mutect2
- SMG7 | c.2802C>T p.L934= | Silent (SNP) | VAF 17/134 reads (13%) | called by muse, mutect2, varscan2
- SPATA13 | c.729C>T p.N243= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs371788710; called by muse, mutect2, varscan2
- SUN5 | c.528C>T p.S176= | Silent (SNP) | VAF 30/265 reads (11%) | catalogued as rs201154490, COSV62182288; called by muse, mutect2, varscan2
- SZT2 | c.6741C>T p.I2247= (on ENST00000634258 / NM_001365999.1; = p.I2190= on NM_015284.4) | Silent (SNP) | VAF 30/92 reads (33%) | called by muse, mutect2, varscan2
- USF3 | c.2814C>T p.C938= | Silent (SNP) | VAF 402/541 reads (74%) | catalogued as rs201434220; called by muse, mutect2, varscan2
- VPS13C | c.5157C>G p.L1719= (on ENST00000644861 / NM_020821.3; = p.L1676= on NM_017684.5) | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV99830804; called by muse, mutect2, varscan2
- ZNF341 | c.603C>T p.P201= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2
- AC013394.1 | c.-71-2926T>G | Intron (SNP) | VAF 34/394 reads (9%) | called by muse, mutect2
- DUSP22 | c.139-9476G>T | Intron (SNP) | VAF 48/308 reads (16%) | catalogued as rs1204024489, COSV60528457; called by muse, varscan2
- MUC19 | n.18033_18034insCAGTGACAGGGAAAAGTGGACTATCAGCTG | RNA (INS) | VAF 78/645 reads (12%) | called by muse*, mutect2
- NAALAD2 | c.1278+123C>T | Intron (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- SLC7A3 | c.*4C>T | 3'UTR (SNP) | VAF 20/130 reads (15%) | catalogued as rs978103355, COSV99979649; called by muse, mutect2, varscan2
